Somatic mutation profile of tumor specimen TCGA-XF-A8HE-01A (aliquot TCGA-XF-A8HE-01A-11D-A364-08) from TCGA case TCGA-XF-A8HE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.1 years (17,212 days).
Specimen TCGA-XF-A8HE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ecad262-8dd1-4691-92b9-b4990c63ec78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HE-10A (Blood Derived Normal), aliquot TCGA-XF-A8HE-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b27ba7cb-0d5d-43ea-b253-6e960192c37f

The open-access MAF lists 440 somatic variants for this specimen: 321 protein-altering or splice-affecting, 111 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 111, Nonsense Mutation 26, Splice Site 4, RNA 3, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 2, Splice Region 2, Intron 2, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACO1 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338965407, COSV59379790; called by muse, mutect2, varscan2
- ACSM5 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59371224; called by muse, mutect2
- ACTL6A | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66998938; called by muse, mutect2, varscan2
- ACTL6A | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV66998940; called by muse, mutect2, varscan2
- ACTL6A | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.735); catalogued as COSV66998944; called by muse, mutect2, varscan2
- ACTL6B | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50514869; called by muse, mutect2
- ADAM17 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs549183501, COSV60398739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM9 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV65946681; called by muse, mutect2, varscan2
- ADCY3 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167392, COSV99567751; called by muse, mutect2, varscan2
- AF196969.1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as CM081571, COSV52141708, COSV52141991; called by muse, mutect2, varscan2
- AHCTF1 | c.257G>A p.G86D (on ENST00000366508; = p.G60D on NM_015446.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58249657; called by muse, mutect2, varscan2
- AHNAK | c.6075C>G p.I2025M | Missense Mutation (SNP) | VAF 68/411 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV57202452, COSV57212829; called by muse, mutect2, varscan2
- AKAP13 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs144259676, COSV63456387; called by muse, mutect2, varscan2
- AKAP13 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs537413224, COSV100773319, COSV63456399; called by muse, mutect2, varscan2
- AKAP13 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs530733643, COSV63456411; called by muse, varscan2
- AKAP13 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV63450744; called by muse, varscan2
- AKAP5 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100278075; called by muse, mutect2, varscan2
- ALG10 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV56792526; called by muse, mutect2, varscan2
- ANP32B | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100233286; called by muse, mutect2
- AOX1 | c.3103G>C p.D1035H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53495926, COSV53496178; called by muse, mutect2, varscan2
- APOBEC3H | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV62378697; called by muse, mutect2, varscan2
- AQP3 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV53048342; called by muse, mutect2, varscan2
- ARFGAP3 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1447645975, COSV54311879; called by muse, mutect2, varscan2
- ARL8B | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99848811; called by muse, mutect2, varscan2
- ARMC4 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99518859; called by muse, mutect2
- ARRB1 | c.843C>G p.N281K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV63575427; called by muse, mutect2, varscan2
- ATP2A1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV63920940; called by muse, mutect2, varscan2
- ATP6V0A4 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs564427621, COSV59474720; called by muse, mutect2, varscan2
- ATPAF1 | c.298G>C p.E100Q (on ENST00000574428; = p.E123Q on NM_022745.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV61304895; called by muse, mutect2, varscan2
- BAZ1A | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV62410532; called by muse, mutect2
- BCL2L11 | c.364C>T p.Q122* (on ENST00000393256 / NM_138621.5; = p.Q62* on NM_006538.5) | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100427483; called by muse, mutect2, varscan2
- BDP1 | c.6358C>G p.Q2120E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100702811, COSV62431267; called by muse, mutect2
- BEST2 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV50367913, COSV99244647; called by muse, mutect2
- BRINP1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV56299462; called by muse, mutect2, varscan2
- BRIP1 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1209325148, COSV51999247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.5393C>G p.S1798C | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1311480859, COSV60895539; called by muse, mutect2, varscan2
- BUD13 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52768231; called by muse, mutect2, varscan2
- CACNA1D | c.4021T>C p.W1341R (on ENST00000350061 / NM_001128840.3; = p.W1361R on NM_000720.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55446410; called by muse, mutect2, varscan2
- CADM3 | c.1197G>C p.*399Yext*128 (on ENST00000368125 / NM_001127173.3; = p.*433Yext*128 on NM_021189.5) | Nonstop Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs1480496468, COSV63672898, COSV63675350; called by muse, mutect2, varscan2
- CADPS2 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV57362475, COSV57364407; called by muse, mutect2
- CAPN2 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54336087; called by muse, mutect2, varscan2
- CASKIN1 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV58876050; called by muse, mutect2
- CASP8 | c.1072C>T p.Q358* (on ENST00000432109 / NM_033355.3; = p.Q375* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as COSV51848610, COSV51849599; called by muse, mutect2, varscan2
- CASZ1 | c.3540C>A p.F1180L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV59735308; called by muse, mutect2, varscan2
- CCT8 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54503949; called by muse, mutect2
- CDK15 | c.468G>C p.L156F (on ENST00000652192 / NM_001366386.2; = p.L105F on NM_139158.2) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634171; called by muse, mutect2, varscan2
- CEACAM6 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52267445; called by muse, mutect2, varscan2
- CEP131 | c.2815G>A p.E939K (on ENST00000269392 / NM_001319228.2; = p.E936K on NM_014984.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs770242250, COSV53953011; called by muse, mutect2, varscan2
- CEP162 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV57619797; called by muse, mutect2
- CEP192 | c.4108G>T p.G1370W | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58063735; called by muse, mutect2, varscan2
- CEP97 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV59124352; called by muse, mutect2, varscan2
- CERK | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV53451193; called by muse, mutect2, varscan2
- CFAP65 | c.5518G>C p.E1840Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV58560755; called by muse, mutect2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHD4 | c.2215G>A p.E739K (on ENST00000357008 / NM_001363606.2; = p.E752K on NM_001273.5) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58900883; called by muse, mutect2, varscan2
- CIC | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV50577030, COSV99360208; called by muse, varscan2
- CIC | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV50546797; called by muse, varscan2
- CIC | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99360214; called by muse, mutect2, varscan2
- CKAP5 | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56367563; called by muse, mutect2, varscan2
- CLPP | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99832239; called by muse, mutect2, varscan2
- CNKSR2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54251787, COSV54255737; called by muse, mutect2, varscan2
- COPS5 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474426; called by muse, mutect2, varscan2
- COX7B | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV100968806; called by muse, mutect2
- CPD | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56712687; called by muse, mutect2
- CREB3L2 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100382258; called by muse, mutect2, varscan2
- CREBZF | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV52629497; called by muse, mutect2, varscan2
- CSF1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV60032978; called by muse, mutect2, varscan2
- CSMD1 | c.8803G>T p.D2935Y (on ENST00000520002; = p.D2934Y on NM_033225.6) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59320859; called by muse, mutect2, varscan2
- CYP2A6 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs780336943, COSV56535165, COSV56536340; called by muse, mutect2, varscan2
- CYP2F1 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.192); catalogued as COSV58527403; called by muse, mutect2, varscan2
- CYP4X1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64150638, COSV64151811; called by muse, mutect2, varscan2
- DCT | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV65468958; called by muse, mutect2, varscan2
- DDHD2 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.493); catalogued as COSV68157813; called by muse, mutect2, varscan2
- DDX55 | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV53016084; called by muse, varscan2
- DFFA | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV65477219; called by muse, mutect2, varscan2
- DGCR8 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61226602; called by muse, mutect2, varscan2
- DHX15 | c.1352T>A p.I451N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61026843; called by muse, mutect2, varscan2
- DIS3L | c.2893G>C p.D965H (on ENST00000319212 / NM_001143688.3; = p.D882H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV56019985; called by muse, mutect2, varscan2
- DNAH1 | c.7228G>A p.E2410K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV70228612; called by muse, mutect2, varscan2
- DNAH17 | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV101103301; called by muse, mutect2
- DNAJA1 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV100438516, COSV58310347; called by muse, mutect2, varscan2
- DOCK4 | c.5558C>A p.S1853Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV70236539; called by muse, mutect2, varscan2
- DOP1B | c.3395C>A p.S1132Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV67693303; called by muse, mutect2, varscan2
- DPYSL2 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60783290; called by muse, mutect2, varscan2
- DRC1 | c.861C>G p.I287M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.793); catalogued as COSV56531159; called by muse, mutect2, varscan2
- DXO | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61713563; called by muse, mutect2, varscan2
- EBF2 | c.1176G>C p.L392F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as COSV68777622; called by muse, mutect2, varscan2
- EEA1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1351822791, COSV59285541; called by muse, mutect2, varscan2
- EFHD1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745364469, COSV51132378; called by muse, mutect2, varscan2
- EIF2AK4 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1409807052, COSV55468174; called by muse, mutect2, varscan2
- EIF3A | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV64961364; called by muse, mutect2, varscan2
- ENAM | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as COSV101253318, COSV68536973; called by muse, mutect2
- EPM2A | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62296229; called by muse, mutect2, varscan2
- ERG | c.1288G>A p.A430T (on ENST00000398919 / NM_001243428.1; = p.A406T on NM_004449.4) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1463420568, COSV55731855; called by muse, mutect2, varscan2
- EVA1A | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52058228; called by muse, mutect2, varscan2
- EXOC4 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, varscan2
- F3 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV61844989; called by muse, mutect2, varscan2
- F5 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1425347786, COSV63123702; called by mutect2, varscan2
- FAM120B | c.2491-1G>A p.X831_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99379916; called by muse, mutect2
- FAM13B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV50366154; called by muse, mutect2, varscan2
- FANCD2OS | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.353); catalogued as COSV55037362, COSV55043748; called by muse, mutect2, varscan2
- FANCM | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs141729590, CM1512826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV70006864; called by muse, mutect2, varscan2
- FBN3 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs1323456583, COSV54460031; called by muse, mutect2, varscan2
- FLT4 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs757667364, COSV56107763; called by muse, mutect2, varscan2
- FOXE1 | c.240C>G p.Y80* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64301228; called by muse, mutect2, varscan2
- FRMPD4 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as COSV66214664; called by muse, mutect2, varscan2
- GABRG3 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760201044, COSV61517730; called by muse, mutect2
- GASK1B | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56706075, COSV56707132; called by muse, mutect2, varscan2
- GLI3 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67885604, COSV67888266; called by muse, mutect2, varscan2
- GNAI3 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV63983741; called by muse, mutect2, varscan2
- GON4L | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV55187410, COSV99675618; called by muse, mutect2, varscan2
- GPRC6A | c.624G>C p.W208C | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1039263992, COSV59952940; called by muse, mutect2, varscan2
- GRK7 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as COSV53822806; called by muse, mutect2, varscan2
- GSDME | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs771163879, COSV61651627, COSV61651863; called by muse, mutect2, varscan2
- GTF3C1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55187575, COSV99852168; called by muse, mutect2
- GZMA | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV57051647, COSV57058778, COSV99696602; called by muse, mutect2, varscan2
- H2AC12 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63616978, COSV99052675; called by muse, mutect2
- H2BC12 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100804565, COSV63616725; called by muse, mutect2, varscan2
- H3C2 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52518397, COSV52518528; called by muse, mutect2, varscan2
- HCAR2 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61024858, COSV61024889; called by muse, mutect2, varscan2
- HDAC9 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV101287317, COSV67767627; called by muse, varscan2
- HERC1 | c.7376C>T p.S2459L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV71247736; called by muse, mutect2
- HMGXB4 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757502367, COSV53333925; called by muse, mutect2, varscan2
- HNRNPC | c.433C>G p.P145A (on ENST00000420743; = p.P132A on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV60144994; called by muse, varscan2
- HOXD8 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1464788792, COSV57485403; called by muse, mutect2, varscan2
- HPS5 | c.1097G>T p.R366I (on ENST00000349215 / NM_181507.2; = p.R252I on NM_007216.4) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61687467; called by muse, mutect2, varscan2
- HSF2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63773879; called by muse, mutect2, varscan2
- HSPA4L | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56545407; called by muse, mutect2, varscan2
- HTR2A | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV66326594, COSV66327249; called by muse, mutect2, varscan2
- HTR3D | c.789C>G p.F263L (on ENST00000382489 / NM_001163646.2; = p.F90L on NM_182537.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1461299249, COSV61914004; called by muse, mutect2, varscan2
- IFNA17 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV69738147; called by muse, mutect2, varscan2
- IFNGR1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.284); catalogued as rs149290101; called by muse, mutect2, varscan2
- IMPA1 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1261209344, COSV56271391, COSV56271762; called by muse, mutect2, varscan2
- IQCC | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV52207202, COSV52208749; called by muse, mutect2
- JAKMIP2 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV54603659, COSV54614101; called by muse, mutect2, varscan2
- KANK4 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62986687; called by muse, mutect2, varscan2
- KATNIP | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV55180090; called by muse, mutect2, varscan2
- KCNJ10 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV63633590; called by muse, varscan2
- KCNJ15 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60810809; called by muse, mutect2, varscan2
- KCNJ8 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.592); catalogued as COSV53716291; called by muse, mutect2, varscan2
- KDM4A | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53513946; called by muse, mutect2, varscan2
- KIAA0100 | c.4647C>A p.F1549L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66492579; called by muse, mutect2, varscan2
- KIAA0232 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as rs1421943749, COSV56925212; called by muse, mutect2, varscan2
- KIAA1841 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs769628991, COSV54374808; called by muse, mutect2, varscan2
- KIF21B | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59757392; called by muse, mutect2, varscan2
- KIF23 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs763331945, COSV52979627; called by muse, mutect2, varscan2
- KMT2C | c.12230C>G p.S4077* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV51522085; called by muse, mutect2, varscan2
- KMT2C | c.11545C>T p.Q3849* | Nonsense Mutation (SNP) | VAF 26/206 reads (13%) | catalogued as COSV100076064; called by muse, mutect2, varscan2
- KMT2C | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV51437122; called by muse, mutect2, varscan2
- KMT2E | c.4672C>G p.Q1558E | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV57573067; called by muse, mutect2
- KNTC1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100338749, COSV61083006; called by muse, mutect2
- KRI1 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57264491; called by muse, mutect2, varscan2
- LAMA2 | c.4468G>A p.D1490N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV70346623; called by muse, mutect2, varscan2
- LCK | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.478); catalogued as COSV60740191; called by muse, mutect2, varscan2
- LIPH | c.951C>G p.F317L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56183877; called by muse, mutect2, varscan2
- LRRC56 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs377700269; called by muse, mutect2, varscan2
- LRRC57 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99535518; called by muse, mutect2, varscan2
- LRRC8B | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58374727; called by muse, mutect2, varscan2
- MACF1 | c.4720G>C p.D1574H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV57120236, COSV99242160; called by muse, mutect2, varscan2
- MACF1 | c.12080C>T p.S4027L (on ENST00000372915; = p.S1960L on NM_012090.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV57120241, COSV57143958; called by muse, mutect2, varscan2
- MAOA | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV58642815; called by muse, varscan2
- MAP3K12 | c.2455C>G p.P819A | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs757542488, COSV57232771; called by muse, mutect2, varscan2
- MAP3K12 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1327654606, COSV57232784; called by muse, mutect2, varscan2
- MCM2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.753); catalogued as COSV54033353; called by muse, mutect2, varscan2
- MDN1 | c.13165G>A p.E4389K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV65521313; called by muse, mutect2, varscan2
- MFSD8 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV56551122; called by muse, mutect2, varscan2
- MROH2B | c.2098G>C p.D700H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68182602, COSV68183781; called by muse, mutect2, varscan2
- MROH5 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101436121; called by muse, mutect2, varscan2
- MSH2 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs781569442, COSV51878990; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCL1 | c.1114G>A p.D372N (on ENST00000306329 / NM_001378206.1; = p.D12N on NM_015210.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60405911; called by muse, mutect2
- MTIF2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as COSV55051460; called by muse, mutect2, varscan2
- MTMR14 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV56004734; called by muse, mutect2, varscan2
- MUC6 | c.6740C>T p.A2247V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.041); catalogued as COSV70141189; called by muse, mutect2, varscan2
- MXRA7 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | PolyPhen probably damaging (0.919); catalogued as rs776109825, COSV63321260; called by muse, mutect2, varscan2
- MYBL2 | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV53829610; called by muse, mutect2, varscan2
- MYO1E | c.3194A>G p.Q1065R | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55686837; called by muse, mutect2, varscan2
- MYOM2 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs746189413, COSV50711529; called by muse, mutect2
- MYOT | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757400809, COSV53514754; called by muse, mutect2, varscan2
- NAV2 | c.6970C>T p.H2324Y (on ENST00000396087 / NM_001244963.2; = p.H2265Y on NM_145117.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60658283; called by muse, mutect2, varscan2
- NEB | c.17971G>A p.E5991K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51374043; called by muse, mutect2, varscan2
- NGDN | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as COSV68142359; called by muse, mutect2, varscan2
- NOL6 | c.2907C>T p.I969= | Splice Region (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53041537; called by muse, mutect2, varscan2
- NPAP1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1441786912, COSV61506747; called by muse, mutect2
- NSD1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV61775946; called by muse, mutect2, varscan2
- NUP205 | c.4299G>C p.Q1433H | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV53658863; called by muse, mutect2, varscan2
- OR8U1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV100163831, COSV56415558; called by muse, mutect2, varscan2
- OR9Q2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100285541, COSV61111885; called by muse, mutect2, varscan2
- OXER1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV54310771; called by muse, mutect2, varscan2
- PAFAH1B3 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50567982; called by muse, mutect2, varscan2
- PAMR1 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV53512029; called by muse, mutect2, varscan2
- PARP6 | c.1764C>A p.D588E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.935); catalogued as COSV53003139; called by muse, mutect2, varscan2
- PBRM1 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449987855, COSV56275393; called by muse, mutect2, varscan2
- PBRM1 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV56275424; called by muse, mutect2
- PCDHGA7 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV53944175; called by muse, mutect2, varscan2
- PCF11 | c.249C>A p.N83K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53530887; called by muse, mutect2, varscan2
- PCF11 | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53527878; called by muse, mutect2, varscan2
- PCLO | c.6889G>C p.E2297Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs773820261, COSV61633973, COSV61674490; called by muse, mutect2, varscan2
- PDLIM4 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1268539572, COSV53804037; called by muse, mutect2, varscan2
- PDLIM7 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs774710389, COSV100730313; called by muse, varscan2
- PDSS1 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.289); catalogued as rs1159086264, COSV66058976; called by muse, mutect2, varscan2
- PEAK1 | c.3959G>C p.G1320A | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV56935011; called by muse, mutect2, varscan2
- PHF7 | c.83delinsTT p.S28Ffs*39 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | catalogued as COSV56234142; called by mutect2*, pindel
- PIK3R3 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV53107099; called by muse, mutect2, varscan2
- PLEKHH3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.067); catalogued as COSV53188900; called by muse, mutect2
- PLK2 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57106455, COSV57108602; called by muse, mutect2, varscan2
- PLXDC2 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV101023914, COSV101025749; called by muse, mutect2
- POGLUT2 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV65683047; called by muse, mutect2, varscan2
- POLA2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV55483095; called by muse, varscan2
- POLQ | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV51751436, COSV99953109; called by muse, mutect2, varscan2
- PPP1R10 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV64739173, COSV64739800; called by muse, mutect2, varscan2
- PPP4R3B | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV55404443; called by muse, mutect2
- PRKDC | c.9418G>A p.E3140K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV58051501; called by muse, mutect2, varscan2
- PRLR | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51495402, COSV51497856; called by muse, mutect2
- PROS1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62398371; called by muse, mutect2
- PROX1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1222008558, COSV54778895; called by muse, mutect2, varscan2
- PRSS58 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.221); catalogued as COSV73488632; called by muse, mutect2
- PSG6 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.257); catalogued as COSV51832842; called by muse, mutect2, varscan2
- PSMD2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773453167, COSV59529641; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1144G>C p.E382Q (on ENST00000421990 / NM_001136042.2; = p.E364Q on NM_025267.3) | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.229); catalogued as COSV64182807; called by muse, mutect2, varscan2
- PTPN4 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs781205857, COSV55301251; called by muse, mutect2, varscan2
- PTPRN2 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV101153380; called by muse, mutect2
- PYGB | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV53818494, COSV99405566; called by muse, mutect2, varscan2
- RAB25 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1008118846, COSV63108038; called by muse, mutect2, varscan2
- RB1CC1 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.69); catalogued as COSV50248215; called by muse, mutect2, varscan2
- RBFA | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV51533762; called by muse, mutect2
- RBMY1E | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV62777090; called by muse, mutect2, varscan2
- RDH10 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs556672044, COSV53582247; called by muse, mutect2, varscan2
- REM2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs1204230900, COSV57465448; called by muse, mutect2, varscan2
- RINL | c.737G>A p.R246K (on ENST00000591812 / NM_001195833.2; = p.R132K on NM_198445.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1386149354, COSV61574647; called by muse, mutect2, varscan2
- RNASE3 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58959453; called by muse, mutect2, varscan2
- RNF111 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV62084870; called by muse, mutect2, varscan2
- RNF216 | c.1477G>T p.E493* (on ENST00000425013 / NM_207116.3; = p.E550* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV101111379; called by muse, mutect2, varscan2
- RNF8 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV57721233, COSV57721500; called by muse, mutect2, varscan2
- ROCK2 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55078574; called by muse, mutect2, varscan2
- RPAP2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV72509310; called by muse, mutect2, varscan2
- RPRD1A | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV59821992; called by muse, mutect2, varscan2
- RUVBL1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59475868; called by muse, mutect2, varscan2
- RXRB | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63399693; called by muse, mutect2, varscan2
- RYR2 | c.12759G>C p.L4253F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV63684386; called by muse, mutect2
- SAFB | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.264); catalogued as COSV52651279; called by muse, mutect2
- SAFB | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751387449, COSV52651287; called by muse, mutect2
- SAFB | c.2722G>T p.D908Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.673); catalogued as COSV52651292, COSV52652226, COSV52653358; called by muse, mutect2
- SAMD15 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53626249; called by muse, mutect2, varscan2
- SAMD9 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV66073730; called by muse, mutect2, varscan2
- SART3 | c.1042C>T p.Q348* (on ENST00000228284; = p.Q330* on NM_014706.4) | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99934406; called by muse, mutect2, varscan2
- SASH1 | c.3596C>T p.S1199F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as COSV66561545; called by muse, mutect2, varscan2
- SBNO1 | c.3623C>T p.S1208L (on ENST00000420886; = p.S1207L on NM_018183.5) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57341526; called by muse, mutect2, varscan2
- SCAI | c.517G>A p.E173K (on ENST00000336505 / NM_001144877.3; = p.E196K on NM_173690.5) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs1436715656, COSV60612684; called by muse, mutect2, varscan2
- SEL1L3 | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.07); catalogued as COSV53535673, COSV53538511; called by muse, mutect2, varscan2
- SEMA4F | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV60283225; called by muse, mutect2, varscan2
- SERPINB13 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs771394755, COSV54028507; called by muse, mutect2, varscan2
- SESN2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV53427520, COSV99456096; called by muse, mutect2, varscan2
- SIRT1 | c.1649C>A p.S550* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV99282018; called by muse, mutect2, varscan2
- SLC23A3 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV99841330; called by muse, mutect2, varscan2
- SLC25A24 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs145306696; called by muse, mutect2, varscan2
- SLC25A5 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58626324; called by muse, mutect2, varscan2
- SLC31A1 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV65264663; called by muse, mutect2, varscan2
- SLC38A10 | c.913-1G>A p.X305_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as rs1297885933, COSV55845307, COSV55846214; called by muse, mutect2, varscan2
- SLC8A2 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52639674; called by muse, mutect2, varscan2
- SLCO4C1 | c.2109A>T p.K703N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60515505; called by muse, mutect2, varscan2
- SLU7 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.709); catalogued as COSV51787617; called by muse, mutect2, varscan2
- SMAD3 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV59283692; called by muse, mutect2, varscan2
- SMC2 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770558864, COSV53957867; called by muse, mutect2, varscan2
- SOCS6 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV67546370; called by muse, mutect2, varscan2
- SP4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV56022581; called by muse, mutect2, varscan2
- SPEF2 | c.2191T>G p.L731V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1188637810, COSV61548104; called by muse, mutect2, varscan2
- ST3GAL1 | c.501C>T p.L167= | Splice Region (SNP) | VAF 18/103 reads (17%) | catalogued as COSV60611145; called by muse, mutect2, varscan2
- SUGT1 | c.724-1G>A p.X242_splice (on ENST00000343788 / NM_001130912.3; = p.X210_splice on NM_006704.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100139667; called by muse, mutect2
- SULT1B1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as COSV100150456; called by muse, mutect2
- TADA2B | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53827269; called by muse, mutect2, varscan2
- TAF3 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV100720466, COSV60206492; called by muse, mutect2, varscan2
- TAF6 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.262); catalogued as COSV59841595; called by muse, mutect2, varscan2
- TAS2R46 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67852338, COSV67855643; called by muse, varscan2
- TBC1D31 | c.2899G>C p.D967H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV54866059; called by muse, mutect2, varscan2
- TEDDM1 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV62380485; called by muse, mutect2, varscan2
- TFDP1 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV64740367; called by muse, mutect2, varscan2
- TG | c.2455C>G p.L819V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV55075381, COSV99603772; called by muse, varscan2
- TG | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV55075391; called by muse, varscan2
- THUMPD3 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.157); catalogued as COSV61505961, COSV61505990; called by muse, mutect2, varscan2
- TIAM1 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54550195; called by muse, mutect2, varscan2
- TLR1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58304225; called by muse, mutect2, varscan2
- TM4SF1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs775442660, COSV100543051, COSV59524872; called by muse, mutect2, varscan2
- TMEM200A | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51652702, COSV51660920; called by muse, mutect2, varscan2
- TMEM63B | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs776687560, COSV52478687; called by muse, mutect2, varscan2
- TNFRSF10A | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV55325756; called by muse, mutect2, varscan2
- TNIP3 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV50247795; called by muse, mutect2, varscan2
- TRAPPC8 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51970726; called by muse, mutect2, varscan2
- TRIM13 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53949371; called by muse, mutect2, varscan2
- TSACC | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100966229; called by muse, mutect2, varscan2
- TSSK6 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53062900; called by muse, mutect2
- TTC23L | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV72205874; called by muse, mutect2, varscan2
- TTN | c.68014C>G p.P22672A (on ENST00000591111; = p.P15248A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | PolyPhen possibly damaging (0.572); catalogued as COSV60044101; called by muse, mutect2, varscan2
- TTN | c.63134C>T p.S21045F (on ENST00000591111; = p.S13621F on NM_003319.4) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | PolyPhen benign (0.444); catalogued as rs1429979686, COSV60044140; called by muse, mutect2, varscan2
- UBN2 | c.2704C>G p.Q902E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV56030121, COSV56032326; called by muse, mutect2
- UBN2 | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as rs773007325, COSV56030140; called by muse, mutect2
- UFL1 | c.1900-1G>A p.X634_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100990138; called by muse, mutect2
- UGGT2 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV65074634; called by muse, mutect2, varscan2
- UNC13B | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs373846094, COSV65931107; called by muse, varscan2
- USP31 | c.3377C>T p.S1126F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs767401137, COSV54852013; called by muse, mutect2, varscan2
- VGF | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1209990073, COSV50800803; called by muse, mutect2
- VPS28 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52871839; called by muse, mutect2
- WDR11 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54784946, COSV54788241; called by muse, mutect2, varscan2
- WDR62 | c.4036C>T p.P1346S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1441625194, COSV54334856, COSV99543496; called by muse, mutect2, varscan2
- WWC2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs138464595; called by muse, mutect2, varscan2
- ZAR1 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51946577; called by muse, mutect2, varscan2
- ZBTB32 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV52890467; called by muse, mutect2, varscan2
- ZNF318 | c.6187G>A p.E2063K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs775867297, COSV58932425; called by muse, mutect2, varscan2
- ZNF384 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100158246, COSV60530379; called by muse, mutect2, varscan2
- ZNF595 | c.1529G>A p.C510Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1460839209, COSV59549776; called by muse, mutect2
- ZNF611 | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as rs1316991513, COSV100160190, COSV100160566; called by muse, mutect2, varscan2
- ZNF611 | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 34/211 reads (16%) | catalogued as COSV100160568; called by muse, mutect2, varscan2
- ZNF611 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100160570; called by muse, mutect2, varscan2
- ZNF611 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60540784; called by muse, mutect2, varscan2
- ZNF620 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1298573119, COSV58820384; called by muse, mutect2, varscan2
- ZNF713 | c.64C>T p.Q22* (on ENST00000633730 / NM_001366796.2; = p.Q35* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs1332811815, COSV101289526, COSV68888196; called by muse, mutect2, varscan2
- ZRANB1 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100456875; called by muse, mutect2, varscan2
- IGKV6D-41 | c.130del p.Q44Rfs*? | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- KMT2D | c.4217dup p.Y1407Lfs*25 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- SGPP2 | c.892del p.Q298Sfs*24 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- ABCA7 | c.714C>T p.L238= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1469111443, COSV54029111; called by muse, mutect2, varscan2
- AC006059.2 | c.1014G>C p.L338= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV59606858; called by muse, mutect2, varscan2
- ACVRL1 | c.1194C>T p.I398= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV66360164; called by muse, mutect2, varscan2
- AGRN | c.5481C>T p.L1827= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1356720500, COSV101038964, COSV101039051; called by muse, mutect2
- ANXA6 | c.486C>T p.L162= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV62906707; called by muse, mutect2, varscan2
- APOBEC3H | c.261C>A p.S87= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs773083408, COSV62378701; called by muse, mutect2, varscan2
- ASCC3 | c.705G>A p.L235= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV61228309; called by muse, mutect2, varscan2
- ASTE1 | c.750G>A p.G250= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs141011294; called by muse, mutect2
- BTG1 | c.474G>A p.T158= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs752016296, COSV55457960; called by muse, mutect2, varscan2
- CATSPERB | c.3195G>A p.A1065= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs775176127, COSV56426229; called by muse, mutect2, varscan2
- CBR1 | c.51C>T p.I17= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99289596; called by muse, mutect2
- CD209 | c.174C>G p.V58= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52652990; called by muse, mutect2, varscan2
- CEP192 | c.6922C>T p.L2308= | Silent (SNP) | VAF 9/222 reads (4%) | catalogued as COSV58063752; called by muse, mutect2
- CIC | c.543G>A p.R181= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV50567979; called by muse, mutect2, varscan2
- CLIC6 | c.2007C>T p.I669= (on ENST00000360731 / NM_001317009.2; = p.I651= on NM_053277.3) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV62447651; called by muse, mutect2, varscan2
- CNDP1 | c.654C>T p.F218= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV62593878; called by muse, mutect2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as rs145203676; called by muse, mutect2
- CPXCR1 | c.561C>T p.F187= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1377535762, COSV52160801, COSV52163490; called by muse, mutect2, varscan2
- CRTC2 | c.1686C>T p.F562= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs769443498, COSV57842707; called by muse, mutect2, varscan2
- CYP2F1 | c.369C>T p.V123= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV58527398; called by muse, mutect2, varscan2
- DENND10 | c.315C>T p.F105= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV63857639; called by muse, mutect2, varscan2
- DLEC1 | c.288C>T p.L96= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV57299417; called by muse, mutect2, varscan2
- DLL1 | c.891C>G p.P297= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100816181; called by muse, mutect2
- DYM | c.1875G>A p.L625= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV53984520; called by muse, mutect2, varscan2
- ENTPD8 | c.1098C>T p.S366= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV58161897; called by muse, mutect2, varscan2
- ERH | c.201C>T p.L67= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53680574; called by muse, mutect2, varscan2
- ERP27 | c.351G>A p.L117= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56763315; called by muse, mutect2, varscan2
- FANCI | c.141G>C p.L47= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV55526759; called by muse, mutect2, varscan2
- FAT4 | c.7992C>A p.V2664= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV58683614; called by muse, mutect2, varscan2
- FN3KRP | c.822G>A p.E274= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV53929694; called by muse, mutect2, varscan2
- FRYL | c.4278C>T p.V1426= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs1195189632, COSV99977978; called by muse, mutect2
- GIT1 | c.2262C>T p.I754= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV56402433; called by muse, mutect2, varscan2
- GLB1L | c.1443C>T p.L481= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55476506; called by muse, mutect2, varscan2
- GPR176 | c.1107C>T p.L369= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs1327227768, COSV54444960; called by muse, mutect2, varscan2
- GTPBP3 | c.444C>T p.F148= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs745687275, COSV50176946; ClinVar: likely benign; called by muse, mutect2, varscan2
- H1-3 | c.135C>T p.I45= | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as rs200463287, COSV55097131, COSV99768859; called by muse, mutect2, varscan2
- HMGB2 | c.459G>A p.E153= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV56633532; called by muse, mutect2, varscan2
- HOXD10 | c.918C>T p.T306= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs376251268; called by mutect2, varscan2
- ICA1L | c.453G>A p.R151= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV64173393; called by muse, mutect2, varscan2
- ILDR2 | c.363G>A p.E121= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99614401; called by muse, mutect2
- KCNN4 | c.729G>A p.L243= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV99487172; called by muse, mutect2
- KCTD7 | c.402C>T p.I134= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs754958440, COSV51876840, COSV99299286; called by muse, mutect2
- KMT2D | c.1800C>T p.F600= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV56438067; called by muse, mutect2, varscan2
- KRI1 | c.219G>A p.L73= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV57264498; called by muse, mutect2, varscan2
- LMNA | c.114C>T p.L38= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1222226105, COSV100738827; called by muse, mutect2, varscan2
- LRP4 | c.63C>T p.S21= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV66135723; called by muse, mutect2, varscan2
- LRRC57 | c.351G>A p.G117= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs201038101, COSV52999975; called by muse, mutect2, varscan2
- LRRC57 | c.240G>A p.E80= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV52999978; called by muse, mutect2, varscan2
- LRRC8B | c.1755C>T p.V585= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58374734; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1281C>T p.I427= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs761801234, COSV53797738; called by muse, mutect2, varscan2
- MASP1 | c.1209G>A p.K403= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV51459750; called by muse, mutect2, varscan2
- MCAM | c.384C>T p.I128= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV50680315; called by muse, mutect2, varscan2
- MDM1 | c.1078C>T p.L360= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57445891; called by muse, mutect2, varscan2
- MED1 | c.3858G>A p.Q1286= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1184694843, COSV56124674; called by muse, mutect2, varscan2
- MEF2A | c.330C>G p.L110= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV57532963; called by muse, mutect2, varscan2
- MGAT5B | c.1590C>T p.F530= (on ENST00000569840 / NM_001199172.2; = p.F528= on NM_144677.3) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV56929044; called by muse, mutect2, varscan2
- MIGA1 | c.1776C>G p.L592= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV66223589; called by muse, mutect2, varscan2
- MINDY4 | c.1986G>A p.L662= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs752777915, COSV54673690; called by muse, mutect2, varscan2
- MUC3A | c.7974C>T p.F2658= | Silent (SNP) | VAF 48/645 reads (7%) | catalogued as rs1563069353, COSV60215374; called by muse, mutect2
- MVB12B | c.426G>A p.R142= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as COSV63257707, COSV63258402; called by muse, mutect2, varscan2
- MYO1G | c.2583G>A p.Q861= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV51854477; called by muse, mutect2, varscan2
- NPBWR2 | c.552C>T p.F184= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs201448282, COSV100871142; called by muse, mutect2
- NPBWR2 | c.165C>T p.I55= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV63900106, COSV63900486; called by muse, varscan2
- NPBWR2 | c.111C>T p.F37= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV63900111; called by muse, varscan2
- NTNG2 | c.756G>A p.L252= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV62366546; called by muse, mutect2, varscan2
- OBSL1 | c.4107C>G p.L1369= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2
- OOSP2 | c.36G>A p.L12= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV53928766; called by muse, mutect2, varscan2
- OR2M2 | c.144C>T p.L48= | Silent (SNP) | VAF 54/270 reads (20%) | catalogued as COSV62898304; called by muse, mutect2, varscan2
- OTUD4 | c.987C>T p.L329= (on ENST00000447906 / NM_001366057.1; = p.L264= on NM_001102653.1) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV101486057; called by muse, mutect2, varscan2
- P4HB | c.906C>T p.L302= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs200781309; called by muse, varscan2
- PACSIN2 | c.954G>A p.K318= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV54319069; called by muse, mutect2, varscan2
- PAPPA | c.3579G>A p.Q1193= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100074384, COSV60282826; called by muse, mutect2, varscan2
- PAXBP1 | c.2721G>A p.V907= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV59507220; called by muse, mutect2
- PGLYRP3 | c.423C>A p.I141= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs139620883, COSV51950115; called by muse, mutect2, varscan2
- PIWIL4 | c.2547C>G p.L849= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV54409201; called by muse, mutect2
- PKD1 | c.3795G>A p.L1265= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV51915985; called by muse, mutect2, varscan2
- PLEKHN1 | c.633C>T p.L211= (on ENST00000379409; = p.L171= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58021779; called by muse, mutect2, varscan2
- PPP1R15B | c.306C>G p.V102= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV65815746; called by muse, mutect2, varscan2
- PRR14 | c.519G>A p.E173= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV54911741; called by muse, mutect2, varscan2
- RIN1 | c.1974C>G p.L658= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV60926414; called by muse, mutect2
- RNF145 | c.114C>T p.I38= (on ENST00000424310 / NM_001199383.2; = p.I66= on NM_144726.2) | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV50866230; called by muse, mutect2, varscan2
- RPL3 | c.858G>A p.K286= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV53365333; called by muse, mutect2, varscan2
- RRAGA | c.720G>C p.L240= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs141987080, COSV65843364; called by muse, mutect2, varscan2
- RSPH6A | c.1374C>T p.F458= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV55571674; called by muse, mutect2, varscan2
- RUBCNL | c.1413C>T p.I471= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1299204615, COSV100529354; called by muse, mutect2, varscan2
- SBF1 | c.3597C>T p.S1199= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs754805260, COSV62367461; called by muse, mutect2, varscan2
- SCO2 | c.72G>A p.G24= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1334816169, COSV52687721; called by muse, mutect2, varscan2
- SGCD | c.765G>T p.T255= (on ENST00000435422 / NM_001128209.2; = p.T256= on NM_000337.5) | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV61908199; called by muse, mutect2, varscan2
- SH3RF2 | c.207C>T p.L69= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs774262685, COSV63038817; called by muse, mutect2, varscan2
- SLC15A3 | c.1152G>A p.L384= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV50005471; called by muse, mutect2
- SLC17A4 | c.171G>A p.L57= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV64956167; called by muse, mutect2, varscan2
- SMARCD3 | c.1212C>T p.I404= (on ENST00000262188 / NM_001003801.2; = p.I391= on NM_003078.4) | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV50390827; called by muse, mutect2
- SOHLH1 | c.657C>T p.F219= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs758782648, COSV53680579; called by muse, mutect2, varscan2
- SPHKAP | c.3360G>A p.S1120= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1018412133, COSV100764506, COSV60878017, COSV60894188; called by muse, mutect2, varscan2
- SPIDR | c.1056C>T p.L352= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52376761; called by muse, mutect2, varscan2
- SYNGAP1 | c.2718C>T p.L906= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV53381194; called by muse, mutect2, varscan2
- TCHH | c.657G>A p.R219= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs201915759, COSV64274707; called by muse, mutect2, varscan2
- TEX37 | c.405C>T p.L135= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1245417979, COSV57555764; called by muse, mutect2, varscan2
- THBS4 | c.300C>A p.L100= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV63469272; called by muse, mutect2, varscan2
- TMPRSS11D | c.879C>G p.L293= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV52223153; called by muse, mutect2, varscan2
- TNFRSF11A | c.1497G>A p.G499= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1327470280, COSV54023361; called by muse, mutect2, varscan2
- TTF2 | c.762G>C p.L254= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as COSV65632579; called by muse, mutect2, varscan2
- TTN | c.23502C>T p.L7834= (on ENST00000591111; = p.L6907= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs772386098, COSV60044186; ClinVar: likely benign; called by muse, mutect2
- TTYH1 | c.813C>G p.L271= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV56611669; called by muse, mutect2, varscan2
- TUBGCP6 | c.4902G>A p.L1634= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs779532804, COSV50544667; called by muse, mutect2, varscan2
- TXLNA | c.1125G>A p.L375= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65314307; called by muse, mutect2, varscan2
- WWC2 | c.3531C>T p.F1177= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100033017; called by muse, mutect2
- YEATS2 | c.1989G>A p.V663= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59365233; called by muse, mutect2, varscan2
- ZNF570 | c.1278T>C p.I426= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1434315435, COSV57579031; called by muse, mutect2, varscan2
- ZNF611 | c.801C>G p.L267= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as COSV60540774; called by muse, mutect2, varscan2
- ZSCAN4 | c.1167C>T p.I389= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV56592652, COSV99989761; called by muse, mutect2, varscan2
- CLCA3P | n.659C>G | RNA (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- FGFR3 | c.*99C>T | 3'UTR (SNP) | VAF 11/66 reads (17%) | catalogued as rs1044021305, CM164529, COSV53400927; called by muse, mutect2, varscan2
- LRP5L | n.673C>G | RNA (SNP) | VAF 21/101 reads (21%) | catalogued as rs1205649543, COSV68602092; called by muse, mutect2, varscan2
- MYL6 | chr12:56161414 G>A | 3'Flank (SNP) | VAF 24/123 reads (20%) | catalogued as COSV99255269; called by muse, mutect2, varscan2
- NRP1 | c.1759+1286G>A | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as rs1433646782, COSV55166378; called by muse, mutect2, varscan2
- OGG1 | chr3:9759253 G>A | 3'Flank (SNP) | VAF 26/126 reads (21%) | catalogued as COSV56538687; called by muse, mutect2, varscan2
- USP32 | c.1239+4614C>G | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100342750; called by muse, mutect2, varscan2
- ZNF271P | n.2054G>A | RNA (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
